Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GG, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GG-01A (Primary Tumor).

[page 1 of 3]
Diagnosis:

Kidney, right, nephrectomy.

- Chromophobe renal cell carcinoma, nuclear grade 3, maximum tumor size 10 cm, tumor confined to kidney with negative surgical margins and no evidence of involvement of the renal artery, renal vein or ureter.

Comment:

Drs. and have additionally reviewed this case and concur with the diagnosis of the chromophobe renal cell carcinoma, nuclear grade 3.

Clinical History:

The patient has a right renal mass.

ICD-O-3
Carcinoma, renal cell
chromophobe type 8317/3
Site R Kidney NOS C64.9
QW 9/24/13

Gross Description:

Received is one appropriately labeled container additionally labeled "right renal mass."

Specimen fixation: formalin

Type of specimen: radical nephrectomy

Size and weight of specimen: 10.0 cm superior to inferior, 14 cm medial to lateral, 7 cm anterior to posterior; 570 grams

Presence/absence of adrenal gland: absent

Tumor description: the tumor is a globoid, well circumscribed by a pseudocapsule, hilar, nodular lesion which on cut surface is softened with yellow/tan color and focal hemorrhage; no central scars are grossly identified

Tumor size: 10 x 8 x 7 cm

Presence/absence of multicentricity: absent

Confinement/Non-confinement to kidney: the tumor is confined by the renal capsule

Extent of invasion:

Perirenal adipose tissue: tumor does not grossly involve

[page 2 of 3]
Renal vein: tumor does not grossly involve
Ureter: tumor does not grossly involve

Surgical margins:
Perirenal adipose tissue: grossly negative
Renal vein: grossly negative
Renal artery: grossly negative
Ureter: grossly negative

Description of kidney away from tumor: the renal cortex is atrophied to 0.5 cm; the calyces are mildly dilated; hydro-ureter is absent

Lymph nodes (hilar): none identified

Tissue submitted for special investigations: none

Comment: The external surface is uniformly inked blue; representative sections are submitted as per block summary.

Block Summary:

A1 - ureteral renal vein and artery resection margins
A2 - tumor interface with renal hilum
A3 - tumor interface with perinephric fat
A4,A5 - representative sections of tumor
A6,A7 - representative sections of non-tumorous kidney

Light Microscopy:

Light microscopic examination is performed by Dr.
Histologic tumor type/subtype: chromophobe renal cell carcinoma,
consistent with eosinophil chromophobe type

Histologic grade (if applicable): nuclear grade 3

Tumor size (greatest dimension): 10 cm

Extent of tumor invasion:
Capsular invasion/perirenal adipose tissue: negative
Renal vein: negative
Ureter: negative
Blood vascular: negative
Lymphovascular: negative
Depth of invasion: not applicable
Adjacent organs: not applicable

Anaplasia (applicable only to Wilm Tumor):

[page 3 of 3]
Presence/absence: not applicable

Extent: not applicable

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Adrenal gland: not present

Lymph nodes: not identified

Other significant findings: The tumor consists of a cellular neoplasm without true encapsulation which shows a predominant solid growth pattern with admixed tubular and trabecular patterns as well as interspersed stromal hyaline fibrosis particularly in the central regions of the tumor. The tumor consists of an admixture of larger polygonal cells with well defined cell borders and amphophilic cytoplasm and large numbers of admixed small polygonal cells with eosinophilic cytoplasm. Distinct perinuclear halos are present in many cells. Many nuclei show hyperchromatic features with markedly irregular nuclear membranes and scattered binucleation. The features are consistent with a chromophobe renal cell carcinoma, eosinophilic type. This case was shown in consultation to Drs. and who concur with the diagnosis of chromophobe renal cell carcinoma, nuclear grade 3.

Source: NCI Genomic Data Commons file c8122bb9-7894-4360-9ffd-1700bd4bc69a (TCGA-UW-A7GG.C8653D2E-3A8C-4C3B-8638-9BC503E7EBC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).